Gene-level copy-number profile of tumor specimen TARGET-10-PASUGC-09A from TARGET case TARGET-10-PASUGC, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 9.6 years (3,515 days).
Specimen TARGET-10-PASUGC-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-ALL-P2.34e6f532-6d99-5f2f-b869-e23161ef72ea.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-10-PASUGC-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 365 have no estimate.
https://portal.gdc.cancer.gov/files/c84f6831-9f4b-42ca-b685-88fe17f0e38d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 66; copy number 1: 2,916; copy number 2: 56,579; copy number 3: 525; copy number 4: 129; copy number 5: 43.

Homozygous deletions (total copy number 0; autosomes only): 66 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:38,256,337–38,340,998, 15 genes: TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7, TRGV6.
- chr7:38,345,030–38,350,022, 2 genes: TRGV5P, TRGV5.
- chr7:142,722,358–142,793,368, 15 genes: PGBD4P1, AC244472.1, TRBV29-1, PRSS1, PRSS2, PRSS3P1, WBP1LP1, TRBD1, TRBJ1-1, TRBJ1-2, TRBJ1-3, TRBJ1-4, TRBJ1-5, TRBJ1-6, TRBC1.
- chr8:39,451,045–39,522,852, 1 gene: ADAM3A.
- chr9:21,802,636–22,029,594, 8 genes: MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A.
- chr9:21,995,482–22,012,536, 3 genes: AL449423.1, CDKN2B, UBA52P6.
- chr11:55,635,113–55,674,675, 4 genes: OR4P4, OR4S2, OR4C6, OR4V1P.
- chr13:48,303,744–48,599,436, 1 gene (within-gene range 0–1): RB1.
- chr13:48,389,567–48,578,088, 7 genes (within-gene range 0–1): LPAR6, Metazoa_SRP, RCBTB2, AL157813.2, AL157813.1, LINC01077, LINC00462.
- chr14:22,197,446–22,482,959, 1 gene (within-gene range 0–1): AC244502.1.
- chr14:22,304,054–22,439,015, 8 genes: TRAV39, TRAV40, TRAV41, AC244502.2, AC244502.3, TRDV2, TRDD1, TRDD2.
- chr16:55,760,566–55,793,960, 1 gene (within-gene range 0–2): CES1P1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 43 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:55,714,799–56,234,255, 43 genes, copy number 5: OR5D2P, OR5D3P, OR5D17P, OR5D13, OR5D15P, OR5D14, OR5L1, OR5D18, OR5L2, OR5D16, OR9M1P, AC036111.2, AC036111.3, AC036111.1, TRIM51, OR5W1P, OR5W2, OR5I1, OR10AF1P, OR10AK1P, OR10AG1, OR7E5P, OR5F1, OR5F2P, OR5AS1, OR5AQ1P, OR5J1P, OR5BE1P, OR8I2, OR8I4P, OR8H2, OR5BN2P, OR8H3, OR5BN1P, OR8J3, OR8K4P, OR8K5, OR5J7P, OR5J2, OR8V1P, AC022882.1, OR8J2, OR5T2.

Autosomal genes at a single copy (total copy number 1): 529. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
